Gene-level copy-number profile of tumor specimen TCGA-VQ-A91S-01A from TCGA case TCGA-VQ-A91S, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: GX; Age at diagnosis: 63.5 years (23,187 days).
Specimen TCGA-VQ-A91S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.ef540c7d-353f-47f9-a0c4-f6cd87322727.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A91S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1df90a5e-0b79-440d-bc89-645cc6cd80f1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 3,315; copy number 2: 36,202; copy number 3: 14,875; copy number 4: 3,891; copy number 5: 669; copy number 6: 367; copy number 7: 126; copy number 8: 128; copy number 9: 12; copy number 11: 17; copy number 15: 2; copy number 18: 84; copy number 19: 7; copy number 20: 107.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A91S-01A-11D-A40Z-01): tumor purity 0.6, ploidy 2.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:110,108,031–110,534,757, 1 gene (within-gene range 0–3): AC073114.1.
- chr11:128,208,749–128,921,163, 11 genes (within-gene range 0–1): LINC02098, ETS1, MIR6090, ETS1-AS1, AP001122.1, FLI1, SENCR, KCNJ1, AP000920.1, KCNJ5, C11orf45.
- chr16:62,596,372–62,598,449, 1 gene: AC009110.1.
- chr22:33,320,865–33,322,813, 1 gene: Z82173.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,519 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:78,148,101–85,540,511, 116 genes, copy number 5 (broad region; genes not listed).
- chr8:86,866,415–95,811,254, 124 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:95,505,406–145,066,685, 783 genes, copy number 5–7 (broad region; genes not listed).
- chr9:14,475–16,061,663, 212 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr9:16,409,503–17,114,122, 10 genes, copy number 5: BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1.
- chr11:86,892,214–87,328,824, 9 genes, copy number 5 (within-gene range 3–5): AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1, AP001102.1.
- chr12:114,548,854–114,898,529, 10 genes, copy number 5: AC069240.1, OSTF1P1, AC010177.1, Y_RNA, TBX3, AC026765.3, AC026765.4, AC026765.1, AC026765.2, AC009804.2.
- chr17:27,612,588–27,894,752, 17 genes, copy number 11: ITM2BP1, AC015688.4, AC015688.6, LGALS9, NOS2P1, AC015688.3, AC015688.5, CPDP1, AC015688.2, AC015688.1, AC130289.1, AC130289.2, LGALS9DP, NOS2, AC005697.1, AC005697.2, LYRM9.
- chr17:29,246,859–29,404,105, 6 genes, copy number 19 (within-gene range 2–19): CRYBA1, NUFIP2, RPL35AP35, AC068025.2, AC068025.1, RNU4-34P.
- chr17:29,390,662–29,390,730, 1 gene, copy number 19: MIR4523.
- chr17:39,603,536–39,747,291, 11 genes, copy number 9: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr17:40,439,467–41,865,423, 108 genes, copy number 15–20 (broad region; genes not listed).
- chr17:41,867,581–41,867,736, 1 gene, copy number 20: AC125257.2.
- chr20:87,250–543,835, 18 genes, copy number 6: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1.
- chr20:51,596,514–52,204,308, 9 genes, copy number 6 (within-gene range 4–6): ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1.
- chr22:20,241,415–21,551,461, 83 genes, copy number 18 (broad region; genes not listed).
- chr22:21,555,138–21,555,457, 1 gene, copy number 18: Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 3,308. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
